Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A6FA, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A6FA-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: M

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering MD:

Copy To:

Specimen(s) Received

1. GE Resection: DISTAL ESOPHAGUS AND PROXIMAL STOMACH RESECTION MARGIN ON BOTH ENDS PLEASE Q.S.
2. Stomach: tip of stomach
3. Esophagus: Final esophageal margin free end final margin

Diagnosis

1. Gastro-esophageal resection: Moderately differentiated invasive squamous cell carcinoma, distal esophagus, PT2N1bMx. 4 of 19 lymph nodes show metastatic deposits (4/19). The tumor invades the entire thickness of the muscularis propria. The proximal and distal margins are clear of tumour. The circumferential margin is not involved but close to tumor (1mm). See synoptic report.

2. Stomach, tip: Negative for malignancy.

3. Esophagus, free end final margin: Focal atypia of squamous mucosa in keeping with high-grade dysplasia. Negative for malignancy.

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Esophagus, distal third
C15.5
JTD 6/10/13

Synoptic Data

Specimen Type:

Tumor Site:

Tumor Size:

Histologic Type:

Histologic Grade:

Pathologic Staging (pTNM):

Margins:

Venous (Large Vessel) Invasion (V):

Esophagogastrectomy

distal esophagus

Greatest dimension: 8.3 cm

Additional dimensions: 5.7 cm

Squamous cell carcinoma

G2: Moderately differentiated

pT2: Tumor invades muscularis propria

pN1b: 4 to 7 nodes involved

Number of lymph nodes examined: 19

Number of lymph nodes involved: 4

Proximal margin-Uninvolved by invasive carcinoma

Distal margin-Uninvolved by invasive carcinoma

Circumferential (Adventitial) margin-Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 1 mm

Margin: circumferential margin

Absent

[page 2 of 3]
Surgical Pathology Consultation Report

Lymphatic (Small Vessel) Invasion (L): Absent
Additional Pathologic Findings: Dysplasia
Other: High grade dysplasia present at final esophageal margin.

Electronically verified by:

Clinical History

ESOPHAGEAL CA

Gross Description

GROSS EXAMINATION

RESECTION SPECIMEN: DISTAL
HOW RECEIVED: FIXED

DIMENSIONS OF ESOPHAGUS:

LENGTH 7CM
CIRCUMFERENCE 7CM

DIMENSIONS OF STOMACH IF PRESENT:

Length along lesser curvature 7cm
Length along greater curvature 9cm
Circumference of distal/gastric margin 18 cm

TUMOR:

- LOCATION: WITHIN GE JUNCTION
- CONFIGURATION: highly ulcerative
- DIMENSIONS: DIAMETERS 8.3 CM X 5.7 CM
DEPTH 1.8 CM
- DESCRIPTIVE CHARACTERISTICS: Solid and tan-white on cut surface
- DISTANCE FROM MARGINS:
PROXIMAL 2.5 cm
DISTAL 4.0 cm
RADIAL 0.05 cm (soft tissue margin closest to deepest tumor penetration)
- ESTIMATED DEPTH OF INVASION: adventitia

LESIONS IN NONCANCEROUS ESOPHAGUS: Non-identified

lesions in the noncancerous stomach: Non identified

LYMPH NODES: Multiple mediastinal and perigastric lymph nodes are retrieved ranging in size from 0.3 x 0.2 x 0.1 cm to 3.8 x 1.6 x 0.7 cm.

Tumor and normal mucosa samples bank: Yes

Representative sections are submitted as follows:

1A en face section of esophageal resection margin, frozen section resubmitted

1B en face section of gastric resection margin closest to tumor, frozen section resubmitted

1C-1G one full thickness longitudinal strip from the esophageal resection margin to gastric mucosa distal to the tumor, sequentially from proximal to distal (includes tumor at deepest invasion).

1H grossly normal gastric mucosa

1I-1K multiple paraesophageal lymph nodes each

1L, 1M one paraesophageal lymph node quadrisectioned

1N, 1O multiple perigastric lymph nodes each

1P-1T each one perigastric lymph node bisected

[page 3 of 3]
Surgical Pathology Consultation Report

1U one perigastric lymph node trisected

2. The specimen container labeled with the patient's name and as "tip of stomach" contains a small segment of closed stapled bowel received in 10% buffered formalin. It measures 5.5 x 3.3 x 3 cm. there is very minimal perigastric fat attached. The serosal surface is smooth and partly congested. On opening, one third of the mucosa is slightly congested. The rest of the mucosa is grossly normal with prominent rugae. No lymph nodes identified within the fat. Representative sections are submitted as follows:

2A resection margin, margin painted with India ink

2B two sections from the congested area.

3. The specimen container labeled with the patient's name and as "final esophageal margin free end final margin" contains a short segment of esophagus received in 10% buffered formalin. It measures 2 cm long and 5 cm in circumference. One end has a staple line and the other end is opened. Both the serosal and mucosal surfaces are grossly unremarkable.

3A the open end margin is submitted in toto en face.

Quick Section Diagnosis

1. Distal esophagus and proximal stomach (for resection margins on both ends):

QS1A: proximal (esophageal) resection margin, EIT en face: negative for malignancy

QS1B: distal (gastric) margin, representative en face section from part of margin closest to tumor: negative for malignancy.

Source: NCI Genomic Data Commons file c0d2b099-81fc-4982-8ff3-5af80a4741f5 (TCGA-JY-A6FA.B1CD2641-EE7A-4543-9F06-4C273ED5CB89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).